Surgical pathology report (de-identified scan), TCGA case TCGA-E6-A1LX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Roswell Park, specimen TCGA-E6-A1LX-01A (Primary Tumor).

[page 1 of 3]
TSS:

1CD-0-3

Adenocarcinoma, Endometrioid, NOS 8380/3

Site: Endometrium C54.1

2/15/11 *lw*

SPECIMENS:

- A. CYST MORGAN AGNI
- B. RIGHT ADNEXA
- C. LEFT ADNEXA
- D. UTERUS
- E. LEFT EXTERNAL ILIAC LYMPH NODES
- F. RIGHT EXTERNAL ILIAC LYMPH NODES
- G. PARA AORTIC LYMPH NODE

DIAGNOSIS:

- A. CYST MORGAGNI:
- ENCAPSULATED FAT NECROSIS CONSISTENT WITH APPENDIC EPIPLOICA.
- B. RIGHT ADNEXA:
- FOLLICULAR CYSTS AND HEMORRHAGIC CORPUS LUTEUM, OVARY.
- BENIGN PARATUBAL CYST, FALLOPIAN TUBE.
- NO TUMOR SEEN.
- C. LEFT ADNEXA:
- FOLLICULAR CYST, OVARY.
- UNREMARKABLE FALLOPIAN TUBE.
- NO TUMOR SEEN.
- D. UTERUS:
- ~~ENDOMETRIOID~~ ADENOCARCINOMA, FIGO GRADE III (SEE TEMPLATE).
- COMPLEX HYPERPLASIA.
- E. LEFT EXTERNAL ILIAC LYMPH NODES:
- FIVE REACTIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/5).
- F. RIGHT EXTERNAL ILIAC LYMPH NODES:
- FOUR REACTIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- G. PARA AORTIC LYMPH NODE:
- THREE REACTIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

ENDOMETRIAL CARCINOMA TEMPLATE:

Prior Biopsy Specimen:	Yes
Prior Biopsy Diagnosis:	Endometrioid adenocarcinoma, Figo I with focal secretory change
Specimen type:	Hysterectomy
Tumor size:	5.5 x 3.4 x 1.0 cm
Histologic type:	Endometrioid
Histologic Grade:	G3
Myometrial invasion:	Present
Depth of invasion/myometrial thickness:	3/21 mm
Venous/lymphatic invasion:	Present
Cervical Involvement:	No
Margins:	Negative
Lymph nodes:	Negative
Other tissue Removed for Staging other than TAHBSO: Adnexa	
Other positive Sites:	None
Other pathologic findings:	None
Peritoneal Cytology:	Negative
Pathologic stage:	pT1b N0 M0

Note: Dr. has reviewed selected slides from the hysterectomy and concurs with this interpretation.
Additional sections will be submitted to identify additional lymph nodes.

[page 2 of 3]
TSS: . . .

SPECIMEN(S):

A. CYST MORGAN AGNI B. RIGHT ADNEXA C. LEFT ADNEXA D. UTERUS E. LEFT EXTERNAL ILIAC LYMPH NODES F. RIGHT EXTERNAL ILIAC LYMPH NODES G. PARA AORTIC LYMPH NODE

CLINICAL HISTORY:

Not given.

GROSS DESCRIPTION:

A. CYST MORGAN AGNI

Received in formalin and labeled "cyst morgan agni" is an oval tan tissue measuring 1.3 x 0.7 x 0.7 cm. On the surface are two polypoid raised white-tan nodules measuring 0.2 cm. each. The tissue is attached to a silver metal clip, by a translucent membrane, measuring 1.4 x 0.4 x 0.4 cm. On sectioning, the tissue has a golden-yellow coloration. Totally submitted in block labeled A1.

B. RIGHT ADNEXA

Received in formalin and labeled with the patient's name and "right adnexa" is a ligated fallopian tube measuring in total 3.3 cm in length with a diameter of 0.7 cm. There is a paratubal cyst measuring 0.2 cm. The ovary measures 3.4 x 2.7 x 0.9 cm and the surface has a cystic appearance. On sectioning, the fallopian tube is unremarkable and the ovary contains several clear fluid cysts ranging in size from 0.3 to 0.9 cm. The cyst walls are free of any masses or papillary lesions. Representative sections are submitted in block B1-B3.

C. LEFT ADNEXA

Received in formalin and labeled with the patient's name and "left adnexa" is a fallopian tube measuring 4.2 cm in length with a diameter of 0.7 cm. There are clear fluid-filled paratubal cysts ranging in size from 0.5 to 0.7 cm. Within the serous membrane is a silver metal clip measuring 1.4 x 0.4 x 0.4 cm. The ovary measures 6.6 x 2.6 x 1.6 cm and there are clear fluid-filled cysts present on the serosal surface ranging in size from 0.4 to 0.8 cm. On sectioning, the fallopian tube is unremarkable and the ovary contains cysts ranging in size from 0.1 to 0.8 cm with the cyst walls free of any masses or papillary lesions. Representative sections are submitted in block C1-C3.

D. UTERUS

Received fresh and labeled and "uterus" is a 162 gram uterus without tubes and ovaries measuring 11.0 x 6.0 x 4.8 cm. There is an attached cervix. The serosal surface is smooth and the ectocervix is unremarkable. The specimen is bivalved to reveal an exophytic friable tan mass filling the endometrial cavity. The myometrium wall thickness measures 2.0 cm and the mass invades 0.4 cm into the myometrium (20%). The mass measures 5.0 x 3.4 x approximately 0.7 cm. Representative sections are submitted as follows:

D1: frozen section

D2-D3: representative sections of cervix

D4-D8: representative sections of endomyometrium, including mass

E. LEFT EXTERNAL ILIAC LYMPH NODES

Received in formalin and labeled with the patient's name and "left external iliac lymph nodes" is an aggregate of yellow-tan fat measuring 3.3 x 3.3 x 0.6 cm. Five possible lymph nodes are found ranging in size from 0.7 to 2.3 cm. The largest lymph node is sectioned and representative sections are submitted as follows:

E1: four possible lymph nodes

E2-E3: one lymph node

F. RIGHT EXTERNAL ILIAC LYMPH NODES

Received in formalin and labeled with the patient's name and "right external iliac lymph nodes" are multiple pieces of yellow-tan fat, an aggregate measuring 4.7 x 3.5 x 0.8 cm. Eight possible lymph nodes are found. The larger ones are bisected and have a variegated pink-tan colorization throughout. Lymph nodes are totally submitted as follows:

F1: four possible lymph nodes

F2-F5: one lymph node each

G. PARA AORTIC LYMPH NODE

Received in formalin and labeled with the patient's name and "para aortic lymph node" is an aggregate of yellow-tan fat measuring 2.7 x 2.3 x 0.5 cm. Three possible lymph nodes are found with lymph nodes submitted as follows:

G1: two possible lymph nodes

G2: bisected lymph node

ADDENDUM:

Additional tissue has been submitted for histologic evaluation.

[page 3 of 3]
TSS: .

- E. LEFT EXTERNAL ILIAC LYMPH NODE:
- ADDITIONAL 4 LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- F. RIGHT EXTERNAL ILIAC LYMPH NODE:
- ADDITIONAL 3 LYMPH NODES, NEGATIVE FOR TUMOR (0/3).
- G. PARA AORTIC LYMPH NODE:
- ADDITIONAL FIBROUS ADIPOSE TISSUE SUBMITTED.
- NO LYMPH NODES IDENTIFIED.

Note: All the fibrous adipose tissue from parts E, F and G have been submitted for histologic evaluation.

Microscopic/Diagnostic Dictation: Pathologist,
Final Review: Pathologist,
Final Review: Pathologist, .
Final: Pathologist,
Addendum: Pathologist,
Addendum Review: Pathologist,
Addendum Final: Pathologist, .
Addendum: Pathologist, .
Addendum Final: Pathologist, .

Source: NCI Genomic Data Commons file 48523261-8012-4d5c-b652-c7c3c20a2e3d (TCGA-E6-A1LX.73CEBF93-0E7C-4EF9-A695-AF489AF3F0F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).